Somatic mutation profile of tumor specimen TCGA-OR-A5K4-01A (aliquot TCGA-OR-A5K4-01A-11D-A29I-10) from TCGA case TCGA-OR-A5K4, project TCGA-ACC (Adrenocortical Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adrenal cortical carcinoma; Tissue or organ of origin: Cortex of adrenal gland; Age at diagnosis: 64.3 years (23,481 days).
Specimen TCGA-OR-A5K4-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 03225695-66c9-4929-97a3-9a207e8ab6bf.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-OR-A5K4-10A (Blood Derived Normal), aliquot TCGA-OR-A5K4-10A-01D-A29L-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/3adc48d7-71c7-4fcb-8bea-d4775b6ce5d7

The open-access MAF lists 221 somatic variants for this specimen: 152 protein-altering or splice-affecting, 68 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 141, Silent 68, Nonsense Mutation 9, Splice Region 1, RNA 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ATM | c.67C>T p.R23* | Nonsense Mutation (SNP) | VAF 100/108 reads (93%) | catalogued as rs746235533, CM024724, COSV53733622; ClinVar: pathogenic; called by muse, mutect2, varscan2
- MSH6 | c.1483C>T p.R495* | Nonsense Mutation (SNP) | VAF 143/157 reads (91%) | catalogued as rs587779212, CM105419, COSV52273723; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP53 | c.1010G>A p.R337H | Missense Mutation (SNP) | VAF 86/92 reads (93%) | hotspot (GDC flag); SIFT tolerated (0.09); PolyPhen possibly damaging (0.719); catalogued as rs121912664, CM012663, CM104660, COSV52665150, COSV52691988, COSV52828545; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TRIOBP | c.3202C>T p.R1068* | Nonsense Mutation (SNP) | VAF 7/37 reads (19%) | catalogued as rs118204030, CD060673, CM067725, COSV100730667; ClinVar: pathogenic; called by muse, mutect2, varscan2
- AGO3 | c.325G>A p.V109I | Missense Mutation (SNP) | VAF 102/114 reads (89%) | SIFT tolerated (0.21); PolyPhen benign (0.086); catalogued as rs1157775569, COSV99868189; called by muse, mutect2, varscan2
- AL645922.1 | c.230G>A p.R77Q | Missense Mutation (SNP) | VAF 3/28 reads (11%) | SIFT tolerated (0.26); PolyPhen benign (0.006); catalogued as rs779595202; called by muse, mutect2
- ANXA1 | c.215G>A p.R72Q | Missense Mutation (SNP) | VAF 64/70 reads (91%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); catalogued as rs750091835, COSV57410292; called by muse, varscan2
- ARMC8 | c.380G>A p.R127Q (on ENST00000469044 / NM_001363941.2; = p.R113Q on NM_014154.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 36/48 reads (75%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.921); catalogued as rs1446398860; called by muse, mutect2, varscan2
- ASPM | c.9592C>T p.R3198C | Missense Mutation (SNP) | VAF 14/44 reads (32%) | SIFT tolerated (0.16); PolyPhen benign (0.065); catalogued as rs760292134, COSV54126456; called by muse, mutect2, varscan2
- ATP11A | c.2888G>A p.R963H | Missense Mutation (SNP) | VAF 94/100 reads (94%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.608); catalogued as rs778847637, COSV52121868; called by muse, mutect2, varscan2
- ATP2A3 | c.2230G>A p.V744M | Missense Mutation (SNP) | VAF 124/130 reads (95%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs753972486; called by muse, mutect2, varscan2
- BCL2L11 | c.553C>T p.R185* (on ENST00000393256 / NM_138621.5; = p.R125* on NM_006538.5) | Nonsense Mutation (SNP) | VAF 92/105 reads (88%) | catalogued as COSV58031349; called by muse, mutect2, varscan2
- BEND3 | c.1561C>T p.R521W | Missense Mutation (SNP) | VAF 23/26 reads (88%) | SIFT deleterious (0); PolyPhen possibly damaging (0.876); catalogued as rs782711728; called by muse, mutect2, varscan2
- C3orf20 | c.188C>T p.P63L | Missense Mutation (SNP) | VAF 112/118 reads (95%) | SIFT tolerated (0.08); PolyPhen benign (0.332); catalogued as rs764690622, COSV53784823; called by mutect2, varscan2
- CD9 | c.317C>T p.A106V | Missense Mutation (SNP) | VAF 89/180 reads (49%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.537); catalogued as rs746317738, COSV99152803; called by muse, mutect2, varscan2
- CDH16 | c.2036G>A p.R679H | Missense Mutation (SNP) | VAF 87/165 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); catalogued as rs565441011, COSV100234307; called by muse, varscan2
- CDH16 | c.1222C>T p.R408* | Nonsense Mutation (SNP) | VAF 75/169 reads (44%) | catalogued as rs758455965; called by muse, mutect2, varscan2
- CEP290 | c.4394G>A p.R1465Q | Missense Mutation (SNP) | VAF 43/95 reads (45%) | SIFT tolerated (0.17); PolyPhen benign (0.015); catalogued as rs576877716, COSV58356962; called by muse, mutect2, varscan2
- CHST8 | c.784G>A p.E262K | Missense Mutation (SNP) | VAF 117/128 reads (91%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52856992; called by muse, mutect2, varscan2
- CKMT2 | c.196G>A p.E66K | Missense Mutation (SNP) | VAF 120/276 reads (43%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs753053736, COSV54174422; called by muse, mutect2, varscan2
- CLK2 | c.413G>A p.R138Q (on ENST00000368361 / NM_001294339.2; = p.R137Q on NM_003993.4) | Missense Mutation (SNP) | VAF 40/49 reads (82%) | SIFT tolerated (0.27); PolyPhen benign (0.007); catalogued as rs1477026654, COSV62877709; called by muse, mutect2, varscan2
- COL5A2 | c.851C>T p.P284L | Missense Mutation (SNP) | VAF 32/34 reads (94%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.988); catalogued as rs540573303; ClinVar: likely benign / uncertain significance; called by muse, varscan2
- CST9 | c.215G>A p.R72H | Missense Mutation (SNP) | VAF 98/233 reads (42%) | SIFT tolerated (0.24); PolyPhen benign (0.015); catalogued as rs1405418371; called by muse, mutect2, varscan2
- CYFIP1 | c.1091C>T p.A364V | Missense Mutation (SNP) | VAF 124/140 reads (89%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.907); catalogued as rs569768747; called by muse, mutect2, varscan2
- DLC1 | c.3643G>A p.V1215I (on ENST00000276297 / NM_001348081.2; = p.V778I on NM_006094.5) | Missense Mutation (SNP) | VAF 102/208 reads (49%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.541); catalogued as rs370207065; called by muse, mutect2, varscan2
- DNAH17 | c.301A>G p.I101V | Missense Mutation (SNP) | VAF 114/123 reads (93%) | SIFT tolerated (0.25); PolyPhen benign (0.012); catalogued as rs775832799; called by muse, mutect2, varscan2
- DUOX2 | c.2732C>T p.S911L | Missense Mutation (SNP) | VAF 156/177 reads (88%) | SIFT deleterious (0.01); PolyPhen benign (0.075); catalogued as rs745729386, CM097376; called by muse, mutect2, varscan2
- ENKD1 | c.832C>T p.R278C | Missense Mutation (SNP) | VAF 40/90 reads (44%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.471); catalogued as rs750759275, COSV54670382; called by muse, mutect2, varscan2
- FABP2 | c.320G>A p.R107Q | Missense Mutation (SNP) | VAF 27/69 reads (39%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.524); catalogued as rs768891255; called by muse, mutect2, varscan2
- FASN | c.6265G>A p.A2089T | Missense Mutation (SNP) | VAF 41/106 reads (39%) | SIFT tolerated (0.68); PolyPhen benign (0.001); catalogued as rs963171358; called by muse, mutect2, varscan2
- FAT1 | c.1316C>A p.T439K | Missense Mutation (SNP) | VAF 90/176 reads (51%) | SIFT tolerated (0.43); PolyPhen benign (0.146); catalogued as COSV71674455; called by muse, mutect2, varscan2
- FBXO10 | c.2570G>A p.R857H | Missense Mutation (SNP) | VAF 103/114 reads (90%) | SIFT tolerated (0.48); PolyPhen benign (0); catalogued as rs747890912, COSV52834298, COSV52835481; called by muse, mutect2, varscan2
- FBXO6 | c.92G>A p.R31H | Missense Mutation (SNP) | VAF 133/149 reads (89%) | SIFT tolerated (0.23); PolyPhen benign (0.26); catalogued as rs146139993; called by muse, varscan2
- FBXW8 | c.1373C>T p.A458V (on ENST00000309909; = p.A496V on NM_012174.1) | Missense Mutation (SNP) | VAF 47/106 reads (44%) | SIFT deleterious (0.01); PolyPhen benign (0.031); catalogued as rs536148392, COSV59303330; called by muse, mutect2, varscan2
- FILIP1L | c.466C>T p.R156* | Nonsense Mutation (SNP) | VAF 76/89 reads (85%) | catalogued as rs757041273; called by muse, mutect2, varscan2
- FRMPD3 | c.823C>T p.R275C | Missense Mutation (SNP) | VAF 85/204 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.741); catalogued as rs1373735369; called by muse, mutect2, varscan2
- GABRB2 | c.1009C>T p.R337C | Missense Mutation (SNP) | VAF 84/194 reads (43%) | SIFT deleterious (0.05); PolyPhen benign (0.031); catalogued as rs777778428, COSV50905153; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- GATA1 | c.163G>A p.A55T | Missense Mutation (SNP) | VAF 75/144 reads (52%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0.27); catalogued as rs150572851, COSV64962467; ClinVar: not provided / benign; called by muse, mutect2, varscan2
- GCN1 | c.866C>T p.T289M | Missense Mutation (SNP) | VAF 21/142 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.096); catalogued as rs374086266, COSV56114841; called by muse, mutect2, varscan2
- GRIK1 | c.346G>A p.V116I | Missense Mutation (SNP) | VAF 13/106 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.403); catalogued as rs142436130; called by muse, mutect2, varscan2
- GTF3C1 | c.4370G>A p.R1457Q | Missense Mutation (SNP) | VAF 57/123 reads (46%) | SIFT tolerated (0.19); PolyPhen benign (0.005); catalogued as rs747237306, COSV100649508; called by muse, varscan2
- IL1RN | c.77G>A p.R26Q (on ENST00000409930 / NM_173842.3; = p.R8Q on NM_000577.5) | Missense Mutation (SNP) | VAF 46/52 reads (88%) | SIFT tolerated (0.26); PolyPhen benign (0.025); catalogued as rs758363942, COSV52080666; called by muse, mutect2, varscan2
- IRF2 | c.122C>T p.A41V | Missense Mutation (SNP) | VAF 33/75 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1255904730, COSV66928316; called by muse, mutect2, varscan2
- KARS1 | c.968G>A p.R323Q | Missense Mutation (SNP) | VAF 98/216 reads (45%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.92); catalogued as rs763872062, COSV56690673; called by muse, mutect2, varscan2
- KATNB1 | c.100C>T p.R34W | Missense Mutation (SNP) | VAF 23/170 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs371850267; called by muse, mutect2, varscan2
- KIAA0753 | c.800G>A p.R267Q | Missense Mutation (SNP) | VAF 54/57 reads (95%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.977); catalogued as rs778952620; called by muse, mutect2, varscan2
- KIAA1217 | c.4306G>A p.V1436M | Missense Mutation (SNP) | VAF 120/129 reads (93%) | SIFT tolerated (0.09); PolyPhen benign (0.351); catalogued as rs372909784; called by muse, mutect2, varscan2
- KIF5A | c.1390G>A p.E464K | Missense Mutation (SNP) | VAF 101/211 reads (48%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.509); catalogued as rs962405110; called by muse, mutect2, varscan2
- KMT2C | c.9529C>T p.R3177C | Missense Mutation (SNP) | VAF 27/28 reads (96%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs145072739; called by muse, mutect2, varscan2
- KRT77 | c.955G>A p.V319I | Missense Mutation (SNP) | VAF 70/140 reads (50%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.978); catalogued as rs375236986; called by muse, mutect2, varscan2
- LETM1 | c.844G>A p.A282T | Missense Mutation (SNP) | VAF 67/148 reads (45%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.59); catalogued as rs1340815089, COSV57104485; called by muse, mutect2, varscan2
- MFSD6 | c.1129G>A p.V377I | Missense Mutation (SNP) | VAF 118/143 reads (83%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.909); catalogued as rs554501896, COSV55622918; called by muse, mutect2, varscan2
- MICU1 | c.776G>A p.R259H (on ENST00000361114 / NM_001195518.2; = p.R265H on NM_006077.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 120/127 reads (94%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs750157034, COSV63144642; called by muse, mutect2, varscan2
- MLLT10 | c.1698C>T p.N566= | Splice Region (SNP) | VAF 31/35 reads (89%) | catalogued as rs778461159; called by muse, mutect2, varscan2
- MON2 | c.2662G>A p.V888M | Missense Mutation (SNP) | VAF 84/184 reads (46%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.803); catalogued as rs201327821, COSV54805911; called by muse, mutect2, varscan2
- MRGPRX4 | c.646G>A p.V216M | Missense Mutation (SNP) | VAF 60/65 reads (92%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.925); catalogued as rs748102743, COSV58590836; called by muse, mutect2, varscan2
- MYH15 | c.2316C>G p.I772M | Missense Mutation (SNP) | VAF 76/82 reads (93%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.82); catalogued as COSV99841920; called by muse, mutect2, varscan2
- MYO18A | c.5140G>A p.E1714K | Missense Mutation (SNP) | VAF 52/61 reads (85%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.949); catalogued as rs763255566; called by muse, mutect2, varscan2
- NCOA6 | c.4394C>T p.S1465L | Missense Mutation (SNP) | VAF 107/201 reads (53%) | SIFT tolerated (0.99); PolyPhen benign (0); catalogued as rs373923954; called by muse, mutect2, varscan2
- NGFR | c.1088C>T p.A363V | Missense Mutation (SNP) | VAF 85/181 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.496); catalogued as rs1315320609, COSV99412845; called by muse, mutect2, varscan2
- NID2 | c.3503G>A p.R1168H | Missense Mutation (SNP) | VAF 68/84 reads (81%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as rs955417276; called by muse, mutect2, varscan2
- NRIP2 | c.596T>C p.L199P | Missense Mutation (SNP) | VAF 11/34 reads (32%) | SIFT tolerated (0.33); PolyPhen benign (0.007); catalogued as rs200104814; called by muse, mutect2, varscan2
- NRIP3 | c.197G>A p.R66K | Missense Mutation (SNP) | VAF 85/95 reads (89%) | SIFT tolerated (0.24); PolyPhen benign (0.01); catalogued as COSV58470850; called by muse, mutect2, varscan2
- PARD3 | c.3985C>T p.R1329W | Missense Mutation (SNP) | VAF 52/57 reads (91%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as rs565005004, COSV61052449; called by muse, mutect2, varscan2
- PCYT2 | c.511C>T p.R171W | Missense Mutation (SNP) | VAF 103/117 reads (88%) | SIFT deleterious (0); PolyPhen possibly damaging (0.613); catalogued as rs544541474; called by muse, mutect2, varscan2
- PIWIL3 | c.869G>A p.R290Q | Missense Mutation (SNP) | VAF 89/96 reads (93%) | SIFT deleterious (0); PolyPhen possibly damaging (0.853); catalogued as rs748965457, COSV59994067, COSV59994372; called by muse, mutect2, varscan2
- PLEC | c.9433C>T p.R3145* (on ENST00000322810 / NM_201380.4; = p.R3035* on NM_000445.5) | Nonsense Mutation (SNP) | VAF 76/146 reads (52%) | catalogued as rs1410984638, COSV100512380; called by muse, mutect2, varscan2
- PLEKHA7 | c.1858G>A p.A620T | Missense Mutation (SNP) | VAF 59/65 reads (91%) | SIFT tolerated (0.48); PolyPhen benign (0); catalogued as rs750416365, COSV100850387; called by muse, mutect2, varscan2
- PLXNA4 | c.1678C>T p.R560W | Missense Mutation (SNP) | VAF 110/122 reads (90%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.676); catalogued as rs374091023; called by muse, mutect2, varscan2
- POU2F1 | c.424G>A p.A142T (on ENST00000541643 / NM_001365848.1; = p.A165T on NM_002697.4) | Missense Mutation (SNP) | VAF 59/133 reads (44%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.978); catalogued as rs774001310, COSV54825934; called by muse, mutect2, varscan2
- PRAG1 | c.2555C>T p.S852L | Missense Mutation (SNP) | VAF 53/132 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1331374191, COSV58159142; called by muse, mutect2, varscan2
- PRDX2 | c.454G>A p.V152M | Missense Mutation (SNP) | VAF 97/107 reads (91%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.878); catalogued as rs758670704; called by muse, mutect2, varscan2
- PRELID3B | c.394G>A p.V132M | Missense Mutation (SNP) | VAF 97/212 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.88); catalogued as rs377376798; called by muse, mutect2, varscan2
- PREX2 | c.468G>T p.K156N | Missense Mutation (SNP) | VAF 87/183 reads (48%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.99); catalogued as rs772266269, COSV55790653; called by muse, varscan2
- PRICKLE2 | c.1966C>T p.R656W (on ENST00000295902; = p.R600W on NM_198859.4) | Missense Mutation (SNP) | VAF 117/131 reads (89%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); catalogued as COSV55771674; called by muse, mutect2, varscan2
- PRPF8 | c.5438G>A p.R1813H | Missense Mutation (SNP) | VAF 148/159 reads (93%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.999); catalogued as COSV59260602; called by muse, mutect2, varscan2
- PTPN23 | c.4133A>G p.Y1378C | Missense Mutation (SNP) | VAF 96/106 reads (91%) | SIFT deleterious (0.04); PolyPhen benign (0.029); catalogued as rs1434120750; called by muse, mutect2, varscan2
- RECQL4 | c.2296C>T p.R766W | Missense Mutation (SNP) | VAF 96/204 reads (47%) | SIFT deleterious (0.01); PolyPhen benign (0.233); catalogued as rs11342077, rs1563028079; called by muse, mutect2, varscan2
- RHOF | c.556C>T p.R186W | Missense Mutation (SNP) | VAF 76/148 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs765693209, COSV57363343; called by muse, varscan2
- RIMS2 | c.4586G>A p.R1529H (on ENST00000666250 / NM_001348490.2; = p.R1100H on NM_014677.5 and 7 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 57/136 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs200286153, COSV51695461; called by muse, mutect2, varscan2
- RNF145 | c.1048G>A p.V350I (on ENST00000424310 / NM_001199383.2; = p.V378I on NM_144726.2) | Missense Mutation (SNP) | VAF 207/475 reads (44%) | SIFT tolerated (0.14); PolyPhen benign (0.28); catalogued as rs778925094, COSV50864802; called by muse, mutect2, varscan2
- RPS6KA4 | c.209C>T p.A70V | Missense Mutation (SNP) | VAF 40/48 reads (83%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as COSV53706626; called by muse, mutect2, varscan2
- RTEL1 | c.601G>A p.G201R | Missense Mutation (SNP) | VAF 60/133 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1192425489, COSV58892642; called by muse, mutect2, varscan2
- SEC16A | c.5165C>T p.T1722M | Missense Mutation (SNP) | VAF 36/42 reads (86%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as rs367852678; called by muse, mutect2, varscan2
- SETBP1 | c.1969G>A p.V657M | Missense Mutation (SNP) | VAF 41/94 reads (44%) | SIFT tolerated (0.08); PolyPhen benign (0.268); catalogued as rs554003194; called by muse, varscan2
- SFI1 | c.995G>A p.R332Q | Missense Mutation (SNP) | VAF 26/108 reads (24%) | SIFT tolerated (0.34); PolyPhen benign (0.003); catalogued as rs762207307; called by muse, mutect2, varscan2
- SH2D4A | c.833G>A p.R278H | Missense Mutation (SNP) | VAF 54/110 reads (49%) | SIFT tolerated (0.1); PolyPhen benign (0); catalogued as rs552781847, COSV56124850; called by muse, mutect2, varscan2
- SKI | c.1268C>T p.P423L | Missense Mutation (SNP) | VAF 80/88 reads (91%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.869); catalogued as rs752779978; called by muse, mutect2, varscan2
- SLC12A7 | c.403G>A p.V135I | Missense Mutation (SNP) | VAF 122/246 reads (50%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.955); catalogued as rs372645005; called by muse, mutect2, varscan2
- SLC4A11 | c.1847C>T p.A616V | Missense Mutation (SNP) | VAF 26/116 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.343); catalogued as rs763428142, COSV66261331; called by muse, mutect2, varscan2
- SMAP2 | c.107C>T p.P36L | Missense Mutation (SNP) | VAF 58/60 reads (97%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs759545887; called by muse, mutect2, varscan2
- SMTNL1 | c.887G>A p.R296H (on ENST00000399154; = p.R333H on NM_001105565.2) | Missense Mutation (SNP) | VAF 52/115 reads (45%) | SIFT tolerated (0.11); PolyPhen benign (0.066); catalogued as rs531246829; called by muse, mutect2, varscan2
- SOX7 | c.502G>A p.G168S | Missense Mutation (SNP) | VAF 35/68 reads (51%) | SIFT tolerated (0.55); PolyPhen benign (0.003); catalogued as rs1249702262, COSV100449013; called by muse, mutect2, varscan2
- SPATA31E1 | c.4103G>A p.R1368H | Missense Mutation (SNP) | VAF 94/105 reads (90%) | SIFT tolerated (0.39); PolyPhen benign (0); catalogued as rs912020310; called by muse, mutect2, varscan2
- SPTBN2 | c.256C>T p.R86W | Missense Mutation (SNP) | VAF 50/106 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs776593274, COSV59451282; called by muse, mutect2, varscan2
- STAB1 | c.5095G>A p.G1699S | Missense Mutation (SNP) | VAF 136/144 reads (94%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs981273519; called by muse, mutect2, varscan2
- STX1B | c.692G>A p.R231H | Missense Mutation (SNP) | VAF 101/231 reads (44%) | SIFT deleterious (0.01); PolyPhen benign (0.31); catalogued as rs1183707872, COSV52682107; called by muse, mutect2, varscan2
- SUSD5 | c.434C>T p.S145L | Missense Mutation (SNP) | VAF 92/107 reads (86%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.886); catalogued as rs776179774, COSV58875454; called by muse, mutect2, varscan2
- TCEAL2 | c.598G>T p.D200Y | Missense Mutation (SNP) | VAF 93/222 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV61197778; called by muse, mutect2, varscan2
- TEDC2 | c.1118G>A p.R373Q | Missense Mutation (SNP) | VAF 30/145 reads (21%) | SIFT tolerated (0.11); PolyPhen benign (0.211); catalogued as rs752195413, COSV62523034; called by muse, mutect2, varscan2
- TJP3 | c.953G>A p.R318Q | Missense Mutation (SNP) | VAF 43/43 reads (100%) | SIFT tolerated (0.27); PolyPhen benign (0.003); catalogued as rs200603772, COSV53660934; called by muse, mutect2, varscan2
- TMC4 | c.934C>T p.R312C (on ENST00000617472 / NM_001145303.3; = p.R306C on NM_144686.4) | Missense Mutation (SNP) | VAF 42/80 reads (53%) | SIFT deleterious (0); PolyPhen benign (0.263); catalogued as rs1384888041, COSV56599459; called by muse, mutect2, varscan2
- TMEM94 | c.638C>T p.P213L | Missense Mutation (SNP) | VAF 38/46 reads (83%) | SIFT tolerated (0.05); PolyPhen benign (0.009); catalogued as rs377628467; called by muse, mutect2, varscan2
- TNPO2 | c.2161G>A p.V721I | Missense Mutation (SNP) | VAF 112/121 reads (93%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.825); catalogued as rs778731425, COSV63507446; called by muse, mutect2, varscan2
- TREML2 | c.305G>A p.R102Q | Missense Mutation (SNP) | VAF 37/53 reads (70%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); catalogued as rs762890750, COSV72438998; called by muse, mutect2, varscan2
- TUBA8 | c.619G>A p.E207K | Missense Mutation (SNP) | VAF 115/133 reads (86%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.941); catalogued as rs770431044, COSV57812804; called by muse, mutect2, varscan2
- TULP4 | c.1027C>T p.R343C | Missense Mutation (SNP) | VAF 49/52 reads (94%) | SIFT deleterious (0.04); PolyPhen benign (0.007); catalogued as rs372249713; called by muse, mutect2, varscan2
- UBR4 | c.6814C>T p.R2272C | Missense Mutation (SNP) | VAF 95/102 reads (93%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs1209286259, COSV64388938; called by muse, mutect2, varscan2
- VPS37B | c.722C>T p.P241L | Missense Mutation (SNP) | VAF 41/65 reads (63%) | SIFT deleterious (0); PolyPhen benign (0.059); catalogued as rs370211610, COSV99458231; called by muse, mutect2, varscan2
- WNT4 | c.1016G>A p.R339Q | Missense Mutation (SNP) | VAF 72/78 reads (92%) | SIFT tolerated (0.36); PolyPhen benign (0.003); catalogued as rs867647835, COSV51603490, COSV51604142; called by muse, mutect2, varscan2
- ZBTB18 | c.1279C>T p.R427C | Missense Mutation (SNP) | VAF 157/172 reads (91%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV62398084; called by muse, mutect2, varscan2
- ZNF135 | c.1873C>T p.R625W (on ENST00000313434 / NM_001289401.2; = p.R637W on NM_003436.4) | Missense Mutation (SNP) | VAF 93/100 reads (93%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.873); catalogued as rs138910447; called by muse, mutect2, varscan2
- ZNF205 | c.1478C>T p.A493V | Missense Mutation (SNP) | VAF 185/347 reads (53%) | SIFT deleterious (0.04); PolyPhen benign (0.13); catalogued as COSV54622178; called by muse, mutect2, varscan2
- ZNF324 | c.925G>A p.G309S | Missense Mutation (SNP) | VAF 201/228 reads (88%) | SIFT deleterious (0); PolyPhen probably damaging (0.935); catalogued as rs1281631170; called by muse, mutect2, varscan2
- ZNF500 | c.985G>A p.E329K | Missense Mutation (SNP) | VAF 77/167 reads (46%) | SIFT deleterious (0.01); PolyPhen benign (0.078); catalogued as rs767538954, COSV54786929; called by muse, mutect2, varscan2
- ZNF648 | c.1373C>T p.A458V | Missense Mutation (SNP) | VAF 21/106 reads (20%) | SIFT tolerated (0.07); PolyPhen benign (0.044); catalogued as COSV60570840; called by muse, mutect2, varscan2
- ZNF785 | c.841G>A p.E281K | Missense Mutation (SNP) | VAF 62/169 reads (37%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.67); catalogued as rs771491092, COSV101235783, COSV101235809; called by muse, mutect2, varscan2
- AP3D1 | c.646A>G p.K216E | Missense Mutation (SNP) | VAF 182/199 reads (91%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- C10orf120 | c.197G>A p.R66K | Missense Mutation (SNP) | VAF 17/60 reads (28%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- CAVIN1 | c.178A>G p.K60E | Missense Mutation (SNP) | VAF 114/126 reads (90%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CDKL5 | c.17T>G p.I6S | Missense Mutation (SNP) | VAF 119/249 reads (48%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.755); called by muse, mutect2, varscan2
- DGCR8 | c.259A>G p.I87V | Missense Mutation (SNP) | VAF 12/81 reads (15%) | SIFT tolerated, low confidence (0.68); PolyPhen benign (0); called by muse, mutect2, varscan2
- DLEC1 | c.193C>T p.R65C | Missense Mutation (SNP) | VAF 144/155 reads (93%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.88); called by muse, mutect2, varscan2
- DLX1 | c.419T>C p.L140S | Missense Mutation (SNP) | VAF 92/101 reads (91%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DNAH1 | c.9860A>G p.D3287G | Missense Mutation (SNP) | VAF 122/133 reads (92%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- ENTPD4 | c.500C>T p.A167V | Missense Mutation (SNP) | VAF 67/126 reads (53%) | SIFT tolerated (0.2); PolyPhen benign (0.102); called by muse, mutect2, varscan2
- FZD8 | c.2027G>A p.R676Q | Missense Mutation (SNP) | VAF 7/15 reads (47%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.715); called by muse, mutect2
- HMCN1 | c.3032C>T p.S1011F | Missense Mutation (SNP) | VAF 51/62 reads (82%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- ITIH1 | c.1709C>T p.T570I | Missense Mutation (SNP) | VAF 167/173 reads (97%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ITPR2 | c.7916G>A p.G2639D | Missense Mutation (SNP) | VAF 54/136 reads (40%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.807); called by muse, mutect2, varscan2
- ITPR2 | c.2789A>G p.Q930R | Missense Mutation (SNP) | VAF 55/132 reads (42%) | SIFT tolerated (0.33); PolyPhen benign (0); called by muse, mutect2, varscan2
- JKAMP | c.881T>C p.L294P (on ENST00000554271 / NM_001284201.1; = p.L280P on NM_016475.5 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 8/104 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); called by muse, mutect2
- JMJD1C | c.829T>C p.Y277H | Missense Mutation (SNP) | VAF 53/59 reads (90%) | SIFT tolerated (0.08); PolyPhen benign (0.076); called by muse, mutect2, varscan2
- KRT12 | c.1363G>A p.A455T | Missense Mutation (SNP) | VAF 69/73 reads (95%) | SIFT tolerated (0.35); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- LRP1 | c.7129C>T p.R2377C | Missense Mutation (SNP) | VAF 25/161 reads (16%) | SIFT tolerated (0.08); PolyPhen benign (0.287); called by muse, mutect2, varscan2
- MAEA | c.95G>A p.R32H | Missense Mutation (SNP) | VAF 166/360 reads (46%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.899); called by muse, mutect2, varscan2
- MDM2 | c.211C>T p.R71* | Nonsense Mutation (SNP) | VAF 25/73 reads (34%) | called by muse, mutect2, varscan2
- MGAT4C | c.284T>C p.L95S | Missense Mutation (SNP) | VAF 55/97 reads (57%) | SIFT tolerated (0.22); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- NAV3 | c.3997C>T p.P1333S | Missense Mutation (SNP) | VAF 43/250 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- NLRP5 | c.2458G>A p.A820T | Missense Mutation (SNP) | VAF 117/128 reads (91%) | SIFT tolerated (0.14); PolyPhen benign (0.074); called by muse, mutect2, varscan2
- NR2C2AP | c.296C>T p.S99L | Missense Mutation (SNP) | VAF 64/74 reads (86%) | SIFT deleterious (0.01); PolyPhen benign (0.266); called by muse, mutect2, varscan2
- PLCB1 | c.359T>G p.V120G | Missense Mutation (SNP) | VAF 77/202 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.124); called by muse, mutect2, varscan2
- PLS1 | c.1080T>A p.N360K | Missense Mutation (SNP) | VAF 60/64 reads (94%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); called by muse, mutect2
- RBM10 | c.1226C>T p.A409V | Missense Mutation (SNP) | VAF 66/341 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- SLC12A8 | c.640T>A p.Y214N | Missense Mutation (SNP) | VAF 80/88 reads (91%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- STAB1 | c.506G>A p.G169E | Missense Mutation (SNP) | VAF 90/105 reads (86%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- TLN2 | c.5291_5326del p.L1764_L1775del | In Frame Del (DEL) | VAF 67/97 reads (69%) | called by mutect2, pindel, varscan2
- TTN | c.18718A>G p.N6240D (on ENST00000591111; = p.N5313D on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 86/92 reads (93%) | PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- VPS35 | c.1658G>A p.W553* | Nonsense Mutation (SNP) | VAF 29/71 reads (41%) | called by muse, mutect2, varscan2
- YTHDF3 | c.694G>A p.A232T | Missense Mutation (SNP) | VAF 118/222 reads (53%) | SIFT tolerated (0.32); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- ZBTB20 | c.347G>A p.R116H (on ENST00000474710 / NM_001164342.2; = p.R43H on NM_015642.6 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 140/154 reads (91%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- ZNF473 | c.2239C>T p.R747C | Missense Mutation (SNP) | VAF 67/72 reads (93%) | SIFT deleterious (0); PolyPhen possibly damaging (0.865); called by muse, mutect2, varscan2
- ABCC9 | c.4272T>C p.I1424= | Silent (SNP) | VAF 12/33 reads (36%) | called by muse, mutect2, varscan2
- ADA | c.828G>A p.T276= | Silent (SNP) | VAF 79/184 reads (43%) | catalogued as rs1269140539; called by muse, mutect2, varscan2
- AIPL1 | c.885G>A p.P295= | Silent (SNP) | VAF 52/56 reads (93%) | catalogued as rs1276719586, CD124712; called by muse, mutect2, varscan2
- AJM1 | c.180C>T p.D60= | Silent (SNP) | VAF 28/32 reads (88%) | catalogued as rs1409348837; called by muse, mutect2, varscan2
- AMT | c.153G>A p.A51= | Silent (SNP) | VAF 102/117 reads (87%) | catalogued as rs768510463; ClinVar: conflicting interpretations of pathogenicity; called by muse, mutect2, varscan2
- ANKRD11 | c.5991G>A p.A1997= | Silent (SNP) | VAF 30/65 reads (46%) | catalogued as rs761021002, COSV99971221; called by muse, mutect2, varscan2
- ARL11 | c.141C>T p.N47= | Silent (SNP) | VAF 129/151 reads (85%) | catalogued as rs751269133; called by muse, mutect2, varscan2
- ASB16 | c.1044G>A p.A348= | Silent (SNP) | VAF 10/30 reads (33%) | catalogued as rs375260670; called by muse, mutect2, varscan2
- BCORL1 | c.5076C>T p.Y1692= | Silent (SNP) | VAF 76/183 reads (42%) | catalogued as rs752053901, COSV54389638, COSV54397195, COSV54408725; called by muse, mutect2, varscan2
- CACNA2D4 | c.3099C>T p.C1033= | Silent (SNP) | VAF 18/26 reads (69%) | catalogued as rs767020808, COSV54956763, COSV54956908; called by muse, mutect2, varscan2
- CASP9 | c.1104C>T p.D368= | Silent (SNP) | VAF 38/43 reads (88%) | catalogued as rs149161953; called by muse, mutect2, varscan2
- CFH | c.1248C>T p.C416= | Silent (SNP) | VAF 134/382 reads (35%) | called by mutect2, varscan2
- COL4A5 | c.333C>T p.G111= | Silent (SNP) | VAF 179/359 reads (50%) | called by muse, mutect2, varscan2
- CYP11A1 | c.1077G>A p.A359= | Silent (SNP) | VAF 67/74 reads (91%) | catalogued as rs987318812, COSV51431482; called by muse, mutect2, varscan2
- DHH | c.1113C>T p.P371= | Silent (SNP) | VAF 60/129 reads (47%) | catalogued as rs1402481543; called by muse, mutect2, varscan2
- DNAAF5 | c.810C>T p.G270= | Silent (SNP) | VAF 73/95 reads (77%) | catalogued as rs762800769; called by muse, mutect2, varscan2
- FAM193B | c.1638G>A p.T546= | Silent (SNP) | VAF 39/97 reads (40%) | catalogued as rs755034614; called by muse, mutect2, varscan2
- FLNA | c.3990C>T p.S1330= | Silent (SNP) | VAF 68/127 reads (54%) | catalogued as rs373659455, COSV61043191, COSV61046633; called by muse, mutect2, varscan2
- GABBR2 | c.702C>T p.N234= | Silent (SNP) | VAF 90/96 reads (94%) | catalogued as rs759372813, COSV52316761; called by muse, mutect2, varscan2
- GAL3ST3 | c.555C>T p.R185= | Silent (SNP) | VAF 51/98 reads (52%) | catalogued as rs1188640745; called by muse, mutect2, varscan2
- GCNT4 | c.633G>A p.S211= | Silent (SNP) | VAF 70/129 reads (54%) | catalogued as rs148761969; called by muse, mutect2, varscan2
- GDF10 | c.990G>A p.A330= | Silent (SNP) | VAF 60/62 reads (97%) | catalogued as rs782407138; called by muse, mutect2, varscan2
- GLG1 | c.3258C>T p.R1086= | Silent (SNP) | VAF 45/235 reads (19%) | catalogued as rs148460697; called by muse, mutect2, varscan2
- GMCL1 | c.1254C>T p.F418= | Silent (SNP) | VAF 61/65 reads (94%) | catalogued as rs746917421; called by muse, mutect2, varscan2
- GRID1 | c.2244C>T p.Y748= | Silent (SNP) | VAF 156/180 reads (87%) | catalogued as rs543588600; called by muse, mutect2, varscan2
- GTPBP10 | c.81C>T p.S27= | Silent (SNP) | VAF 86/94 reads (91%) | catalogued as rs770392847; called by muse, varscan2
- HAUS7 | c.96C>T p.S32= | Silent (SNP) | VAF 139/306 reads (45%) | catalogued as rs1202300650; called by muse, mutect2, varscan2
- HDAC1 | c.387G>A p.T129= | Silent (SNP) | VAF 65/72 reads (90%) | catalogued as rs571782325, COSV101000519; called by muse, mutect2, varscan2
- IGDCC3 | c.1941C>T p.I647= | Silent (SNP) | VAF 36/121 reads (30%) | catalogued as rs1013686495; called by muse, mutect2, varscan2
- ISM1 | c.759G>A p.S253= | Silent (SNP) | VAF 96/211 reads (45%) | catalogued as rs1283525883, COSV52604623; called by muse, mutect2, varscan2
- ITIH5 | c.2163C>T p.N721= | Silent (SNP) | VAF 66/75 reads (88%) | catalogued as rs561325808, COSV53669690; called by muse, mutect2, varscan2
- JCAD | c.3820C>T p.L1274= | Silent (SNP) | VAF 37/40 reads (93%) | called by muse, mutect2, varscan2
- KCNH1 | c.2850G>A p.Q950= (on ENST00000271751 / NM_172362.3; = p.Q923= on NM_002238.4) | Silent (SNP) | VAF 29/81 reads (36%) | called by muse, mutect2, varscan2
- KDM4B | c.2556C>T p.C852= | Silent (SNP) | VAF 35/39 reads (90%) | catalogued as rs1358834221, COSV50219547; called by muse, mutect2, varscan2
- KMT2D | c.15576G>A p.L5192= | Silent (SNP) | VAF 80/169 reads (47%) | catalogued as rs779137584; called by muse, mutect2, varscan2
- KRT7 | c.246C>A p.P82= | Silent (SNP) | VAF 56/128 reads (44%) | called by muse, mutect2, varscan2
- LARP7 | c.1146C>T p.S382= | Silent (SNP) | VAF 26/266 reads (10%) | catalogued as rs1459276751, COSV60521699; called by muse, mutect2
- LMNB1 | c.987T>C p.A329= | Silent (SNP) | VAF 163/337 reads (48%) | called by muse, mutect2, varscan2
- LRP1 | c.6867C>A p.A2289= | Silent (SNP) | VAF 106/247 reads (43%) | called by muse, mutect2, varscan2
- LRRC14 | c.42G>A p.Q14= | Silent (SNP) | VAF 98/184 reads (53%) | called by muse, mutect2, varscan2
- MAML1 | c.1182C>A p.S394= | Silent (SNP) | VAF 59/120 reads (49%) | called by muse, mutect2, varscan2
- MAMLD1 | c.1203C>T p.P401= | Silent (SNP) | VAF 81/180 reads (45%) | catalogued as rs375892884, COSV53378976; called by muse, mutect2, varscan2
- NCKAP5 | c.2478T>A p.P826= | Silent (SNP) | VAF 103/108 reads (95%) | called by muse, mutect2, varscan2
- NR2F6 | c.1008C>T p.T336= | Silent (SNP) | VAF 28/30 reads (93%) | catalogued as rs1160307270, COSV52244797; called by muse, mutect2, varscan2
- NUMB | c.1245C>T p.T415= (on ENST00000355058; = p.T404= on NM_003744.5) | Silent (SNP) | VAF 31/44 reads (70%) | catalogued as rs578172055; called by muse, mutect2, varscan2
- NYX | c.1134C>T p.F378= | Silent (SNP) | VAF 102/191 reads (53%) | catalogued as rs1438907414, COSV61180540; called by muse, mutect2, varscan2
- PAQR4 | c.288C>T p.S96= | Silent (SNP) | VAF 60/128 reads (47%) | catalogued as rs372876046; called by muse, varscan2
- PDLIM7 | c.753G>A p.T251= | Silent (SNP) | VAF 114/223 reads (51%) | catalogued as rs1195544023; called by muse, mutect2
- PGBD4 | c.1644C>T p.Y548= | Silent (SNP) | VAF 44/49 reads (90%) | catalogued as rs1229981343, COSV56629303; called by muse, mutect2, varscan2
- PIGV | c.879G>A p.P293= | Silent (SNP) | VAF 157/170 reads (92%) | catalogued as rs147229452; ClinVar: uncertain significance / likely benign; called by muse, mutect2, varscan2
- PIWIL4 | c.1803C>T p.C601= | Silent (SNP) | VAF 40/45 reads (89%) | called by muse, mutect2, varscan2
- PPP6R2 | c.279C>T p.S93= | Silent (SNP) | VAF 17/46 reads (37%) | catalogued as rs777425517, COSV99324342; called by muse, mutect2, varscan2
- RASGRF1 | c.1233C>T p.Y411= | Silent (SNP) | VAF 74/79 reads (94%) | catalogued as rs774077272, COSV101369798; called by muse, mutect2, varscan2
- RPL10L | c.201C>T p.A67= | Silent (SNP) | VAF 72/85 reads (85%) | catalogued as rs1201929924, COSV53560059; called by muse, mutect2, varscan2
- RTEL1 | c.1011C>T p.D337= | Silent (SNP) | VAF 35/104 reads (34%) | catalogued as rs755186853; called by muse, mutect2, varscan2
- RYR1 | c.162G>A p.A54= | Silent (SNP) | VAF 95/113 reads (84%) | catalogued as rs769042961; ClinVar: likely benign; called by muse, mutect2, varscan2
- SDK1 | c.4011G>A p.S1337= | Silent (SNP) | VAF 79/84 reads (94%) | catalogued as rs537498277; called by muse, mutect2, varscan2
- SEMA3F | c.354C>T p.F118= | Silent (SNP) | VAF 195/224 reads (87%) | catalogued as rs200273983; called by muse, mutect2, varscan2
- SGSM2 | c.447G>A p.A149= | Silent (SNP) | VAF 60/64 reads (94%) | catalogued as rs764611087, COSV52159049; called by muse, mutect2, varscan2
- SGTB | c.357A>C p.A119= | Silent (SNP) | VAF 40/80 reads (50%) | called by muse, mutect2, varscan2
- SIGLEC1 | c.3987C>A p.A1329= | Silent (SNP) | VAF 22/52 reads (42%) | called by muse, mutect2, varscan2
- SLC25A23 | c.1062C>T p.A354= | Silent (SNP) | VAF 60/60 reads (100%) | catalogued as rs148491192, COSV51197787; called by muse, mutect2, varscan2
- SLC7A1 | c.1833G>A p.A611= | Silent (SNP) | VAF 40/41 reads (98%) | catalogued as rs763739976; called by muse, mutect2, varscan2
- SPG7 | c.1365C>T p.D455= (on ENST00000268704; = p.D462= on NM_003119.4) | Silent (SNP) | VAF 119/258 reads (46%) | catalogued as rs1210240025; called by muse, mutect2, varscan2
- TENM2 | c.6462C>T p.F2154= (on ENST00000518659 / NM_001122679.2; = p.F1915= on NM_001080428.3) | Silent (SNP) | VAF 81/184 reads (44%) | catalogued as rs369031454, COSV69125368; called by muse, mutect2, varscan2
- TRO | c.1461A>G p.E487= | Silent (SNP) | VAF 272/604 reads (45%) | catalogued as rs771513063; called by muse, varscan2
- ZBP1 | c.825C>T p.H275= | Silent (SNP) | VAF 24/125 reads (19%) | catalogued as rs370372910; called by muse, mutect2, varscan2
- ZNF213 | c.1191C>T p.G397= | Silent (SNP) | VAF 105/257 reads (41%) | catalogued as rs1010995501, COSV101205921; called by muse, mutect2, varscan2
- PLEKHA8P1 | n.1594G>A | RNA (SNP) | VAF 110/261 reads (42%) | catalogued as rs145353585; called by muse, mutect2, varscan2
